Gene-level copy-number profile of tumor specimen C3L-06061-54 from CPTAC case C3L-06061, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 61.0 years (22,275 days).
Specimen C3L-06061-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1edadfac-02da-4a91-96ba-1c1f7a40c06b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06061-51 (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/03d68872-bcaa-4d97-8244-be69bcd0bb0c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 15; copy number 2: 8,781; copy number 3: 863; copy number 4: 46,533; copy number 5: 442; copy number 6: 2,244.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:151,771,045–153,903,223, 13 genes (within-gene range 0–2): G3BP1, GLRA1, AC091982.2, RNA5SP198, LINC01933, AC008571.2, NMUR2, AC008571.1, LINC01470, GRIA1, RN7SL177P, LINC01861, AC091962.1.
- chr5:155,397,291–157,059,119, 12 genes (within-gene range 0–2): AC010591.1, AC008725.1, RNA5SP199, SGCD, AC011351.1, AC027308.1, AC025434.1, RNU6-556P, PPP1R2B, TIMD4, APOOP1, HAVCR1.
- chr5:157,104,788–157,114,900, 1 gene (within-gene range 0–2): AC011377.1.
- chr5:163,460,203–163,494,058, 2 genes: HMMR, HMMR-AS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
